Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1X9, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1X9-01A (Primary Tumor).

[page 1 of 2]
Department of Cancer Pathology

copy No.:

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: **Total organ resection – left breast with axillary tissues**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: **up to 8 working days**Clinical diagnosis: **Cancer of the left breast.**

ICD-0-3

carcinoma, infiltrating duct, nos 8500/3

Site: breast, nos C50.9

w 4/12/11

Examination performed on:

Results of immunohistochemical examination:

Estrogen receptors found in over 75% of neoplastic cell nuclei. Progesterone receptors found in over 75% of neoplastic cell nuclei. HER2 protein stained with HercepTest™ by DAKO. Score = 2+, FISH verification recommended.

Compliance validated by:

Examination performed on:

Macroscopic description:

Left breast sized 22 x 15 x 5 cm removed along with axillary tissues sized 13 x 7.5 x 1.5 cm and a skin flap of 19 x 11 cm.

Retracted nipple. Tumour sized 2.5 x 2 x 2.8 cm found on the boundary of lower quadrants, located 3.5 cm from the lower boundary, 0.4 cm from the base and 3 cm from the skin.

Microscopic description:

Carcinoma ductale invasivum - NHG2 (2+2+3/21 mitoses/10 HPF - visual area 0.57mm). Glandular tissue showing lesions of the type mastopathia fibrosa et cystica, hyperplasia ductalis simplex (UDH).

AXILLARY LYMPH NODES:

Metastases carcinomatosae in lymphonodis (No III/XXIII).

Infiltratio capsulae lymphonodorum.

Histopathological diagnosis:

Carcinoma ductale invasivum mammae sinistae.

Invasive ductal carcinoma of the left breast.

Metastases carcinomatosae in lymphonodosi axillae (No III/XXIII) (NHG2, pT2, pN1a).

Cancer metastases of axillary lymph nodes (No III/XXIII) (NHG2, pT2, pN1a).

Compliance validated by:

Examination performed on:

Case is (re)filed		☒

[page 2 of 2]
Examination: Histopathological examination

page 2 / 2

Examination No.:

Patient: XXX

PESEL: XXX

Gender: F

Examination performed on: .

Results of immunohistochemical examination:

RESULT OF HER2/neu GENE AMPLIFICATION with the FISH method by Path Vysion HER2 DNA Probe Kit

FINAL RESULT:

HER-2 GENE AMPLIFICATION NOT FOUND

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 5bf8643d-223f-4ecd-a41d-9509e14edde5 (TCGA-D8-A1X9.E69CF3E3-4799-4892-87E9-4291B14A1B9C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).